Gene-level copy-number profile of tumor specimen ALCH-B0CD-TTP1-A from ALCHEMIST case ALCH-B0CD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 85.8 years (31,331 days).
Specimen ALCH-B0CD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c53ebef0-7881-4279-85b2-ee90df1dfb9f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0CD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/28634ba1-f0a9-419a-a952-ea9e9bc16cfd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 3,498; copy number 2: 53,399; copy number 3: 1,137; copy number 4: 632; copy number 5: 97; copy number 6: 76; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,693,124–7,700,970, 3 genes (within-gene range 0–2): AL359881.3, AL359881.2, AL359881.1.
- chr2:231,559,903–231,586,327, 2 genes: RPL21P35, RPL23AP26.
- chr2:231,706,895–231,713,551, 3 genes (within-gene range 0–2): PTMA, U4, MIR1244-1.
- chr2:232,406,844–232,548,115, 9 genes (within-gene range 0–2): ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND, CHRNG.
- chr7:66,505,155–66,592,397, 4 genes (within-gene range 0–2): AC008267.1, AC008267.3, AC006001.3, AC006001.4.
- chr9:66,942,703–66,992,583, 6 genes: AL353770.4, AL353770.2, FAM74A3, AL353770.3, AL353770.1, SPATA31A3.
- chr15:25,176,832–25,250,940, 41 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr18:37,273,706–37,276,572, 1 gene (within-gene range 0–2): AC090386.1.
- chr19:11,585,246–11,587,135, 1 gene (within-gene range 0–2): GAPDHP76.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 174 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:67,210,408–67,467,308, 3 genes, copy number 5: AL591004.1, AL365503.1, RNA5SP208.
- chr7:19,695,461–21,381,506, 26 genes, copy number 5: POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11, RNU1-15P.
- chr7:54,185,071–55,678,490, 26 genes, copy number 5: AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1.
- chr7:110,108,031–110,534,757, 1 gene, copy number 6 (within-gene range 4–6): AC073114.1.
- chr7:110,662,644–117,230,176, 84 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr12:66,302,493–68,451,663, 30 genes, copy number 5 (within-gene range 4–5): HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1.
- chr21:43,414,483–43,479,534, 4 genes, copy number 6–11: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 1,154. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
